MMRF case MMRF_1461 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d226bd95-2f64-47c1-a230-1a2243e683a6

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Dead; Days to death: 1,033 days (2.8 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.4 years (26,097 days); ISS stage: II; Days to last known disease status: 1,033 days (2.8 years); Days to last follow up: 1,033 days (2.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 53 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 56 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 107 days; Days to treatment end: 107 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 108 days; Days to treatment end: 108 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 508 days (1.4 years); Days to treatment end: 815 days (2.2 years).
   Treatment given: Therapeutic agents: Dexamethasone + Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 823 days (2.3 years); Days to treatment end: 831 days (2.3 years).
   Treatment given: Therapeutic agents: Carfilzomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 850 days (2.3 years); Days to treatment end: 865 days (2.4 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Panobinostat; Regimen or line of therapy: Fifth line of therapy; Days to treatment start: 878 days (2.4 years); Days to treatment end: 962 days (2.6 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide + Panobinostat; Regimen or line of therapy: Sixth line of therapy; Days to treatment start: 969 days (2.7 years); Days to treatment end: 1,003 days (2.7 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,033.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 0): M Protein 1.77 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 123 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.203 mg/dL; Immunoglobulin G 3.51 g/L; Immunoglobulin A 22.5 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 4.26 µg/mL; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.45 mmol/L; Albumin 42 g/L; Total Protein 7.5 g/dL; Glucose 6.22 mmol/L.
- Day 74 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 4.66 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 2.11 µg/mL; Lactate Dehydrogenase 10.4 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 32 g/L; Total Protein 5.4 g/dL; Glucose 3.19 mmol/L.
- Day 148 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.736 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.83 mg/dL; Immunoglobulin G 7.71 g/L; Immunoglobulin A 1.02 g/L; Immunoglobulin M 0.62 g/L; Lactate Dehydrogenase 9.74 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 11.6 ×10⁹/L; Absolute Neutrophil 6.6 ×10⁹/L; Platelets 255 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 33 g/L; Total Protein 5.8 g/dL; Glucose 5.01 mmol/L.
- Day 220 (ECOG 3): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.711 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Immunoglobulin G 7.87 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.12 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 6.27 mmol/L.
- Day 304 (ECOG 2): Immunoglobulin G 10.7 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.45 mmol/L; Glucose 5.01 mmol/L.
- Day 416 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.776 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 10.3 mmol/L; Leukocytes 11.1 ×10⁹/L; Absolute Neutrophil 8.1 ×10⁹/L; Platelets 226 ×10⁹/L.
- Day 539 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.95 mg/dL; Immunoglobulin G 8.52 g/L; Immunoglobulin A 1.11 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 9.6 ×10⁹/L; Absolute Neutrophil 6.9 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 6.3 g/dL; Glucose 6.11 mmol/L.
- Day 640 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.94 mg/dL; Immunoglobulin G 5.59 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 3.77 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 5.8 g/dL; Glucose 6.55 mmol/L.
- Day 760 (ECOG 2): Hemoglobin 8.25 mmol/L; Leukocytes 10.2 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.15 mmol/L; Albumin 35 g/L; Total Protein 6 g/dL; Glucose 7.54 mmol/L.
- Day 795 (ECOG 2): Hemoglobin 8.06 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 8.58 mmol/L.
- Day 906 (ECOG 2): Hemoglobin 7.38 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 187 ×10⁹/L.
- Day 1,004 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.274 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 0.6 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.04 g/L; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 46 g/L; Total Protein 6 g/dL; Glucose 5.39 mmol/L.

Other clinical attributes
- Day -7: Weight: 108 kg; Height: 177 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1461_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_1461_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
